Surgical pathology report (de-identified scan), TCGA case TCGA-B7-A5TJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Cureline, specimen TCGA-B7-A5TJ-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					male	Caucasian (White)	Gastric cancer		Stomach, fundus	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Stomach intestinal Adenocarcinoma	3	4	0	0	none	n/a	45
					male	Caucasian (White)	Gastric cancer		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-0-3

Adenocarcinoma, intestinal type 8144/3

Site: Gastric fundus C16.1
JW 4/29/13

Source: NCI Genomic Data Commons file 274064db-9af0-44af-bd4d-9edcf46239ba (TCGA-B7-A5TJ.85DAD347-F0CD-4EDC-9AEC-21653CA2EB4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).